Gene-level copy-number profile of tumor specimen TCGA-CV-7091-01A from TCGA case TCGA-CV-7091, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 54.6 years (19,938 days).
Specimen TCGA-CV-7091-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.774e2a78-a716-4144-8f90-f03d9d8383c8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7091-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dc8bcd6b-c7a1-4126-9192-c3d0553f3a73

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 674; copy number 2: 26,704; copy number 3: 19,498; copy number 4: 8,998; copy number 5: 1,575; copy number 6: 328; copy number 7: 751; copy number 8: 646; copy number 10: 425; copy number 11: 30; copy number 14: 12; copy number 15: 128; copy number 21: 13; copy number 33: 12; copy number 45: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7091-01A-11D-2010-01): tumor purity 0.45, ploidy 2.82, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:138,278,574–138,501,698, 6 genes (within-gene range 0–2): RPL15P5, YWHAEP5, IDI1P1, RNF14P1, AC114763.1, AC114763.2.
- chr4:85,475,150–86,002,668, 2 genes (within-gene range 0–1): ARHGAP24, MIR4451.
- chr13:28,232,501–28,232,607, 1 gene: RNU6-82P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,898 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:179,099,330–180,890,279, 42 genes, copy number 6 (within-gene range 3–6): ABL2, AL512326.5, SETP10, AL512326.2, AL512326.1, EIF4A1P11, AL512326.3, COX5BP8, AL512326.4, SOAT1, AXDND1, MEF2AP1, HNRNPA1P54, AL160286.3, NPHS2, RNU5F-2P, AL160286.1, AL160286.2, TDRD5, AL359853.2, FAM163A, AL359853.1, LINC02818, TOR1AIP2, AL353708.3, TOR1AIP1, RN7SL230P, AL353708.2, AL353708.1, CEP350, RPSAP16, AL590632.1, AL390718.1, QSOX1, LHX4, ACBD6, VDAC1P4, MIR3121, OVAAL, Y_RNA, XPR1, U6.
- chr2:61,803,143–63,197,037, 36 genes, copy number 6 (within-gene range 4–6): RPS24P7, AC108039.2, FAM161A, RPL31P30, AC107081.2, CCT4, AC107081.1, AC107081.3, COMMD1, Y_RNA, AC018462.1, RPSAP26, AC018462.2, B3GNT2, MIR5192, RN7SL51P, AC093159.2, AC093159.1, RN7SL18P, TMEM17, RPL37P13, RPL21P37, AC092155.1, PSAT1P2, RSL24D1P2, EHBP1, Y_RNA, AC092567.2, AC092567.1, RPS20P9, AC007098.1, OTX1, AC009501.1, AC009501.2, RPL27P5, DBIL5P2.
- chr2:63,168,600–63,168,847, 1 gene, copy number 6: Metazoa_SRP.
- chr2:189,762,704–194,612,145, 58 genes, copy number 7–21: OSGEPL1-AS1, AC013468.1, ORMDL1, PMS1, C2orf88, TERF1P6, HNRNPCP2, RNF11P1, MSTN, HIBCH, INPP1, MFSD6, AC093388.1, NEMP2, AC108047.1, RN7SKP179, AC006460.2, NAB1, AC006460.1, AC005540.1, GLS, STAT1, RAB1AP1, AC067945.1, AC067945.2, STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27, AC092614.1, MYO1B, RNU6-1045P, NABP1, AC114778.1, NABP1-OT1, AC098872.1, CAVIN2, CAVIN2-AS1, DNAJB1P1, TMEFF2, AC062039.1, AC013401.1, PCGEM1, RPS17P8, AC013401.2, AC096647.1, SLC44A3P1, DNAJC17P1, SEC61GP1, AC074290.1, AC068135.2, AC068135.1, GLULP6, HNRNPA1P47, LINC01821, AC106883.1, AC073973.1.
- chr3:123,282,296–123,449,090, 1 gene, copy number 5 (within-gene range 4–5): ADCY5.
- chr3:123,490,820–198,222,513, 1,366 genes, copy number 5–14 (broad region; genes not listed).
- chr4:65,142,703–77,494,286, 249 genes, copy number 6 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 5–7 (broad region; genes not listed).
- chr7:70,972–67,362,950, 1,276 genes, copy number 5–11 (broad region; genes not listed).
- chr12:63,844,700–64,162,217, 1 gene, copy number 15 (within-gene range 4–15): SRGAP1.
- chr12:64,032,412–70,920,738, 158 genes, copy number 7–45 (within-gene range 2–45) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 674. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
